Somatic mutation profile of tumor specimen 0DLX5B from CCDI case PBBZTT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 10.3 years (3,759 days).
Specimen 0DLX5B: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e04b218-fb08-4113-ac63-74b4693d45b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLX4L (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f4e4d16-d669-43b6-8db5-5d64d0ba8d35

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN3A | c.3284A>G p.N1095S | Missense Mutation (SNP) | VAF 20/508 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.343); called by muse, mutect2
- B4GALNT1 | chr12:57622833 C>G | 3'Flank (SNP) | VAF 46/1046 reads (4%) | catalogued as COSV57544239; called by muse, mutect2
- MRNIP | c.*44G>A | 3'UTR (SNP) | VAF 57/235 reads (24%) | called by muse, mutect2, varscan2
